CCDI case PBCMJC — CCDI-MCI: Molecular Characterization Initiative (MCI)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Neoplasms, NOS; Primary site: Brain.
https://portal.gdc.cancer.gov/cases/aa897099-4689-4c57-a12d-d824d96652b7

Demographics
Sex at birth: female; Ethnicity: hispanic or latino.

Diagnoses (1)
1. Subependymoma: ICD-O-3 morphology code: 9383/1; Tissue or organ of origin: Brain, NOS; Age at diagnosis: 16.7 years (6,112 days).

Biospecimens (3 samples)
- Sample 0DV5RW: Tissue type: Normal; Specimen type: Peripheral Whole Blood.
- Sample 0DV5S8: Tissue type: Tumor; Specimen type: Solid Tissue.
- Sample 0DV5SH: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: FFPE.
